TCGA case TCGA-CQ-6227 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: University Health Network, Toronto. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5d227ea8-bd74-4e8f-9bee-9d981f03d66f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 77 years; Vital status: Dead; Days to death: 129 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 77.9 years (28,466 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T3; AJCC pathologic N: N2c; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 8; Lymph nodes tested: 59; Lymphatic invasion present: No; Margin status: Indeterminate; Perineural invasion present: Yes; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 129 days; Disease response: With Tumor.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 3; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 20; Tobacco smoking onset year: 1959; Tobacco smoking quit year: 1979.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CQ-6227-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.6; Intermediate dimension: 0.3; Shortest dimension: 0.2.
  Slide TCGA-CQ-6227-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-CQ-6227-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
- Sample TCGA-CQ-6227-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CQ-6227-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Cavity; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Margin status: Close; Lymphovascular invasion: No; Tobacco smoking history indicator: 3; Alcohol consumption frequency: 7.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 129 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 129 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 129 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CQ-6227-01A-11D-1910-01): tumor purity 0.33, ploidy 1.88, whole-genome doublings 0.
